Somatic mutation profile of tumor specimen BA3298D (aliquot aq-BA3298D) from BEATAML1.0 case 2803, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia with t(8;21)(q22;q22), RUNX1-RUNX1T1; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.9 years (24,421 days).
Specimen BA3298D: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 570b51d1-cc15-4e0e-ac93-462c514050eb.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA3148D (Solid Tissue Normal), aliquot aq-BA3148D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd3d22b4-f342-4c26-8135-d8a1776cb32e

The open-access MAF lists 17 somatic variants for this specimen: 14 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 11, Silent 3, Frame Shift Ins 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ANKRD26 | c.4418G>A p.G1473D | Missense Mutation (SNP) | VAF 128/284 reads (45%) | SIFT tolerated (0.08); PolyPhen benign (0.199); catalogued as rs766658322, COSV65778979; called by muse, mutect2, varscan2
- APOB | c.12742G>T p.D4248Y | Missense Mutation (SNP) | VAF 40/261 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV104373675; called by muse, mutect2, varscan2
- DNAH10 | c.5501G>A p.R1834Q (on ENST00000409039; = p.R1773Q on NM_207437.3) | Missense Mutation (SNP) | VAF 42/156 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs916125970, COSV68989405; called by muse, mutect2, varscan2
- KMT2B | c.7085C>T p.P2362L | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs781596697; called by muse, mutect2, varscan2
- MAGEL2 | c.2134A>G p.K712E | Missense Mutation (SNP) | VAF 5/112 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.057); catalogued as rs1395357697; called by muse, mutect2
- PTPRZ1 | c.6645G>T p.R2215S | Missense Mutation (SNP) | VAF 30/202 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.461); catalogued as COSV66444903; called by muse, mutect2, varscan2
- TET2 | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 40/181 reads (22%) | catalogued as COSV99483401; called by muse, mutect2, varscan2
- ENPEP | c.2743T>C p.Y915H | Missense Mutation (SNP) | VAF 48/147 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.317); called by muse, mutect2
- EPHA5 | c.1350G>T p.L450F | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- GALNT2 | c.680G>A p.C227Y | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GIGYF2 | c.2310_2311insGGGG p.R771Gfs*52 | Frame Shift Ins (INS) | VAF 12/142 reads (8%) | called by mutect2, pindel
- SLITRK3 | c.937A>C p.M313L | Missense Mutation (SNP) | VAF 56/366 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TRIM41 | c.832_833insACGAAGGACTTCC p.V278Dfs*53 | Frame Shift Ins (INS) | VAF 10/92 reads (11%) | called by mutect2, pindel
- ZNF99 | c.1490C>A p.T497N | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- CFAP54 | c.5970C>T p.I1990= | Silent (SNP) | VAF 98/180 reads (54%) | called by muse, mutect2
- PCARE | c.1194G>A p.Q398= | Silent (SNP) | VAF 45/124 reads (36%) | called by muse, mutect2, varscan2
- TTC14 | c.27G>A p.S9= | Silent (SNP) | VAF 6/85 reads (7%) | called by muse, mutect2
